Somatic mutation profile of tumor specimen TCGA-G4-6302-01A (aliquot TCGA-G4-6302-01A-11D-1719-10) from TCGA case TCGA-G4-6302, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-G4-6302-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b61126ff-59f5-4024-b5a5-1041c5c23246.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6302-10A (Blood Derived Normal), aliquot TCGA-G4-6302-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53a41a92-c54f-46c8-84fa-bd9bb8d31b24

The open-access MAF lists 1,034 somatic variants for this specimen: 786 protein-altering or splice-affecting, 230 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 600, Silent 230, Frame Shift Del 90, Nonsense Mutation 46, Splice Site 17, Frame Shift Ins 15, Intron 8, Splice Region 8, In Frame Del 6, RNA 4, 5'UTR 3, Translation Start Site 2.

Variants (750 of 1,034; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CIC | c.4544G>A p.R1515H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50551019, COSV50551998; called by muse, mutect2
- DGKE | c.610del p.T204Qfs*6 | Frame Shift Del (DEL) | VAF 40/407 reads (10%) | catalogued as rs147972030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 49/222 reads (22%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 22/277 reads (8%) | catalogued as rs80358374, CM1212035, COSV56946915; ClinVar: pathogenic; called by muse, mutect2
- TTN | c.56008C>T p.R18670* (on ENST00000591111; = p.R11246* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 47/477 reads (10%) | catalogued as rs869312055, CM1514595, COSV59955046; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1282G>A p.G428R (on ENST00000373993 / NM_138932.2; = p.G420R on NM_014576.4) | Missense Mutation (SNP) | VAF 66/581 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50959608; called by muse, mutect2, varscan2
- AAAS | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766985003, COSV52932493; called by muse, mutect2, varscan2
- AACS | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs1446176410; called by muse, mutect2
- AAMP | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs1203351663, COSV50307148; called by muse, mutect2
- AATK | c.695G>A p.R232H (on ENST00000326724 / NM_001080395.3; = p.R129H on NM_004920.2) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200466748, COSV58686257; called by muse, mutect2
- ABCA13 | c.2528C>G p.S843* | Nonsense Mutation (SNP) | VAF 20/136 reads (15%) | catalogued as COSV70026970; called by muse, mutect2, varscan2
- ABCA3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57051189; called by muse, mutect2
- ABCB1 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs28381914; called by muse, mutect2
- ABCC1 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358799070, COSV60682590, COSV60696751; called by muse, mutect2
- ABCC10 | c.1765G>T p.D589Y (on ENST00000372530 / NM_001198934.2; = p.D546Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV55085861; called by muse, mutect2, varscan2
- ABCC3 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53319005; called by muse, mutect2, varscan2
- ABCF1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1277226850, COSV100400858; called by muse, mutect2, varscan2
- ABCF1 | c.2445G>T p.Q815H (on ENST00000326195 / NM_001025091.2; = p.Q777H on NM_001090.3) | Missense Mutation (SNP) | VAF 20/601 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); catalogued as COSV100400860, COSV58230056; called by muse, mutect2
- ABTB1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs776861310, COSV51740531, COSV51740838; called by muse, mutect2, varscan2
- ACAD11 | c.296T>C p.F99S | Missense Mutation (SNP) | VAF 38/418 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53894738; called by muse, mutect2
- ACTL9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as rs782524837, COSV61005237; called by muse, mutect2, varscan2
- ADAM10 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 77/712 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53050173; called by muse, mutect2, varscan2
- ADAM11 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.556); catalogued as rs1431631547, COSV52345163; called by muse, mutect2, varscan2
- ADAM30 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as rs1454902574, COSV65560218, COSV65560365; called by muse, mutect2, varscan2
- ADAMTS1 | c.1211-1G>T p.X404_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | catalogued as COSV53169296; called by muse, mutect2, varscan2
- ADAMTS14 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV100941611; called by muse, mutect2, varscan2
- ADAMTS14 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64600699; called by muse, mutect2
- ADAMTS17 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV51475876; called by muse, mutect2
- ADCY3 | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs760801151, COSV53165763; called by muse, mutect2
- ADGRF1 | c.1849del p.S617Afs*12 | Frame Shift Del (DEL) | VAF 24/205 reads (12%) | catalogued as rs1344904964; called by mutect2, pindel, varscan2
- ADGRL1 | c.1375G>A p.A459T (on ENST00000340736 / NM_001008701.3; = p.A454T on NM_014921.5) | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV61564063; called by muse, mutect2
- AEBP1 | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV56256378; called by muse, mutect2
- AGAP2 | c.2269G>A p.V757I (on ENST00000547588 / NM_001122772.2; = p.V421I on NM_014770.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs1438547158, COSV57727394; called by muse, mutect2
- AGMO | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV61108690; called by muse, mutect2, varscan2
- AGPS | c.1859G>A p.G620D | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51562203; called by muse, mutect2, varscan2
- AHNAK | c.3983T>C p.V1328A | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); catalogued as COSV57208166; called by muse, mutect2
- AHNAK | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775816508, COSV57208175; called by muse, mutect2, varscan2
- AHNAK2 | c.11014G>C p.V3672L | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs758999554, COSV60911247; called by muse, mutect2, varscan2
- AKAP9 | c.4858C>T p.R1620* | Nonsense Mutation (SNP) | VAF 34/280 reads (12%) | catalogued as rs551980172, COSV62341912; called by muse, mutect2, varscan2
- AKNAD1 | c.2039G>T p.C680F | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs866205366, COSV62196467, COSV62198398; called by muse, mutect2
- AL121899.2 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101198469, COSV67351237; called by muse, mutect2
- ALDH1A1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs762664992, COSV52793255; called by muse, mutect2
- AMER1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV57660818; called by muse, mutect2
- AMMECR1 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as COSV53316897; called by muse, mutect2, varscan2
- ANK2 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52152477; called by muse, mutect2
- ANKAR | c.731T>C p.M244T | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV55610903; called by muse, mutect2, varscan2
- ANKLE2 | c.340G>T p.G114* | Nonsense Mutation (SNP) | VAF 26/222 reads (12%) | catalogued as COSV61708419; called by muse, mutect2, varscan2
- ANKRD1 | c.917T>A p.L306H | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV65467337; called by muse, mutect2, varscan2
- ANKRD11 | c.5185G>A p.A1729T | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs368667754; called by muse, mutect2
- ANKRD27 | c.2913G>T p.L971F | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV60130066; called by muse, mutect2
- ANKRD33 | c.713C>A p.S238Y (on ENST00000340970 / NM_001304459.2; = p.L430I on NM_182608.4) | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56605361; called by muse, mutect2, varscan2
- ANO7 | c.354G>T p.E118D (on ENST00000274979; = p.E63D on NM_001001666.4) | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV99238457; called by muse, mutect2
- ANO9 | c.772-3del | Splice Region (DEL) | VAF 22/160 reads (14%) | catalogued as rs535142896; called by mutect2, pindel, varscan2
- AOC2 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53198583; called by muse, mutect2, varscan2
- AP2A2 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766681589, COSV59958952; called by muse, mutect2
- APEH | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV56515022; called by muse, mutect2, varscan2
- APOB | c.10503G>T p.K3501N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.913); catalogued as COSV51929005; called by muse, mutect2, varscan2
- APOB | c.4351G>T p.G1451C | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as rs970842288, COSV51929034; called by muse, mutect2
- ARAP2 | c.3137T>G p.F1046C | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58284440; called by muse, mutect2, varscan2
- ARFGAP2 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53564248; called by muse, mutect2, varscan2
- ARFGEF2 | c.3911G>T p.R1304M | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV100904272; called by muse, mutect2
- ARFGEF3 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1296992061, COSV52453114; called by muse, mutect2
- ARHGAP20 | c.2591A>T p.Y864F | Missense Mutation (SNP) | VAF 67/658 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV52808602; called by muse, mutect2, varscan2
- ARHGAP25 | c.309C>A p.N103K (on ENST00000409202 / NM_001007231.3; = p.N96K on NM_014882.3) | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV54900431; called by muse, mutect2, varscan2
- ARHGAP9 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as rs749408492, COSV57359633; called by muse, mutect2, varscan2
- ARHGEF11 | c.4109C>T p.P1370L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1320754898, COSV59353016; called by muse, mutect2
- ARHGEF39 | c.385A>G p.R129G | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100526244; called by muse, mutect2
- ARIH2 | c.1257+1G>A p.X419_splice | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as COSV62704235; called by muse, mutect2, varscan2
- ARMC5 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51656926; called by muse, mutect2
- ARSJ | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV59537262; called by muse, mutect2, varscan2
- ASH1L | c.8272A>G p.T2758A (on ENST00000368346 / NM_001366177.2; = p.T2753A on NM_018489.3) | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100853435; called by muse, mutect2
- ASH1L | c.7991G>A p.R2664H (on ENST00000368346 / NM_001366177.2; = p.R2659H on NM_018489.3) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.109); catalogued as rs201394353; called by muse, mutect2, varscan2
- ASTN2 | c.3471G>T p.K1157N (on ENST00000313400 / NM_001365069.1; = p.K1106N on NM_014010.5) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56001348; called by muse, mutect2
- ASXL1 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100039414; called by muse, mutect2
- ATF6B | c.1022A>G p.Q341R | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1412685342, COSV64351512; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 25/160 reads (16%) | catalogued as rs771531141; called by mutect2, varscan2
- ATP10A | c.3136G>A p.V1046M | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1171281079, COSV100791282; called by muse, mutect2
- ATP1A3 | c.527G>T p.R176L (on ENST00000545399 / NM_001256214.2; = p.R163L on NM_152296.5) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57486269; called by muse, mutect2
- ATP1A4 | c.2777C>T p.T926M | Missense Mutation (SNP) | VAF 47/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1397211130, COSV100927561; called by mutect2, varscan2
- ATP8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650033, COSV54942586; called by muse, mutect2
- AUTS2 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs376868075; called by muse, mutect2
- AWAT2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV52142991; called by muse, mutect2
- BASP1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV59471768; called by muse, mutect2
- BBS9 | c.1946T>C p.I649T (on ENST00000242067 / NM_001348036.1; = p.I609T on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/369 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1399102946, COSV54161274; called by muse, mutect2
- BCL11A | c.2003C>T p.P668L (on ENST00000335712 / NM_001365609.1; = p.P702L on NM_018014.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100186902, COSV59626704; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 15/153 reads (10%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDP1 | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs1319135679; called by muse, mutect2
- BEX1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 67/668 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1045065, COSV65580026; called by muse, mutect2, varscan2
- BICC1 | c.2917C>T p.R973C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs543889839, COSV65857767; called by muse, mutect2, varscan2
- BMP8A | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs1460803803; called by muse, mutect2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 17/176 reads (10%) | catalogued as rs751941533; called by mutect2, pindel
- BNC2 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV66143291; called by muse, mutect2, varscan2
- BOLA1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV64966727; called by muse, mutect2
- BPIFB2 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50063511; called by muse, mutect2
- BRF1 | c.1025del p.G342Afs*36 | Frame Shift Del (DEL) | VAF 16/164 reads (10%) | catalogued as COSV104402591; called by mutect2, pindel
- BRWD3 | c.1789C>A p.H597N | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100956108; called by muse, mutect2
- BSG | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61076594; called by muse, mutect2
- BSN | c.9061C>T p.R3021W | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs145365460; called by muse, mutect2
- C11orf53 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV54721154; called by muse, mutect2, varscan2
- C16orf92 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV99662452; called by muse, mutect2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | catalogued as rs747134922; called by mutect2, pindel
- C5orf15 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99198325; called by muse, mutect2
- C8B | c.122A>T p.N41I | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV64776927; called by muse, mutect2, varscan2
- C9orf72 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs773251849, COSV66154655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs777088645, COSV53405825; called by muse, mutect2, varscan2
- CACNA2D1 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 40/878 reads (5%) | catalogued as rs1554348754, COSV100666707; called by muse, mutect2
- CACNG7 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV55813691; called by muse, mutect2
- CACTIN | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as rs756257561, COSV50267279; called by muse, mutect2
- CAMK2D | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 46/439 reads (10%) | catalogued as COSV56427931; called by muse, mutect2, varscan2
- CAMK4 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | catalogued as rs1174385043, COSV56674166, COSV56676876; called by muse, mutect2
- CASKIN1 | c.3380G>A p.R1127H | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100399550; called by muse, mutect2
- CATSPERE | c.2169T>A p.D723E | Missense Mutation (SNP) | VAF 55/1014 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100835178; called by muse, mutect2
- CBFA2T3 | c.427T>C p.C143R | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV51924819; called by muse, mutect2, varscan2
- CBLN1 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs953763338, COSV54653608; called by muse, mutect2
- CC2D1A | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs1158465072, COSV58782033; called by muse, mutect2, varscan2
- CC2D2B | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 24/300 reads (8%) | catalogued as COSV100729446; called by muse, mutect2
- CCDC38 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 113/1077 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717650; called by muse, mutect2, varscan2
- CCDC63 | c.1692A>C p.*564Cext*? | Nonstop Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99960777; called by muse, mutect2, varscan2
- CCL2 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs148937652; called by muse, mutect2
- CCNT2 | c.1744A>G p.S582G | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs182667340, COSV51471810; called by mutect2, varscan2
- CD93 | c.1188C>A p.C396* | Nonsense Mutation (SNP) | VAF 32/209 reads (15%) | catalogued as COSV55662900, COSV55664133, COSV55664768; called by muse, mutect2, varscan2
- CDC42BPG | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.153); catalogued as rs760698253, COSV61346322; called by muse, mutect2, varscan2
- CDH10 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV52574871; called by muse, mutect2
- CDH5 | c.2194G>T p.G732C | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58516627, COSV58519189; called by muse, mutect2
- CDH9 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 46/539 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs780851499, COSV50260752; called by muse, mutect2
- CDK5RAP2 | c.5426G>A p.G1809D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1226533181, COSV62573044; called by muse, mutect2, varscan2
- CELF4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58446645; called by muse, mutect2, varscan2
- CELSR1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1486747954, COSV53086106; called by muse, mutect2
- CELSR2 | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as rs376939074; called by muse, mutect2
- CEP164 | c.1854G>A p.M618I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54039592; called by muse, mutect2
- CEP170 | c.4222A>G p.R1408G | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60507446; called by muse, mutect2
- CEP72 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV53791305; called by muse, mutect2
- CERS1 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55928891; called by muse, mutect2, varscan2
- CFAP74 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1380870743, COSV54564656; called by muse, mutect2
- CFTR | c.2869C>T p.L957F | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as CD1413658, COSV50044685; called by muse, mutect2, varscan2
- CFTR | c.3227C>A p.T1076N | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.704); catalogued as COSV50044715; called by muse, mutect2
- CH25H | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100897357; called by muse, mutect2
- CHAC1 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV71435996; called by muse, mutect2
- CHD5 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99313728; called by muse, mutect2
- CHD7 | c.4193C>T p.A1398V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418259; called by muse, mutect2
- CHD9 | c.4616G>A p.C1539Y | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54608897; called by muse, mutect2, varscan2
- CHL1 | c.2581C>T p.H861Y (on ENST00000397491 / NM_001253387.1; = p.H877Y on NM_006614.4) | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.456); catalogued as COSV56598317, COSV99851301; called by muse, mutect2
- CHRNA6 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52378938; called by muse, mutect2
- CHRNB2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 77/830 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765202298, COSV63807902; called by muse, mutect2
- CHST15 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as rs767543459, COSV60561012; called by muse, mutect2
- CHST5 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV60338024; called by muse, mutect2, varscan2
- CILP2 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as rs1303020006, COSV52273505; called by muse, mutect2, varscan2
- CLMP | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV71649455; called by muse, mutect2, varscan2
- CLSPN | c.3234A>T p.E1078D | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV52048483; called by muse, mutect2
- CLSTN2 | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV71719341; called by muse, mutect2
- CLTC | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs142283994; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 19/197 reads (10%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CMTM5 | c.487C>A p.L163M (on ENST00000339180 / NM_001288746.2; = p.L96M on NM_138460.3) | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59304989, COSV59305270; called by muse, mutect2, varscan2
- CNTNAP1 | c.3491T>C p.L1164P | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52848873; called by muse, mutect2, varscan2
- CNTNAP4 | c.2621A>T p.N874I | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56671696; called by muse, mutect2
- CNTRL | c.876A>T p.K292N | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53045024; called by muse, mutect2
- COG6 | c.1064G>T p.R355M | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100742938; called by muse, mutect2
- COG8 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs760792801, COSV54742045; called by muse, mutect2, varscan2
- COL4A6 | c.3691C>T p.R1231* | Nonsense Mutation (SNP) | VAF 25/185 reads (14%) | catalogued as COSV57861982; called by muse, mutect2, varscan2
- COL6A3 | c.9475G>A p.E3159K | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV55084130; called by muse, mutect2, varscan2
- CPNE6 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV99393474; called by muse, mutect2
- CPNE9 | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as rs1288128815, COSV56068751; called by muse, mutect2
- CPXM1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.102); catalogued as rs780342169, COSV66044653; called by muse, mutect2, varscan2
- CRMP1 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271891; called by muse, mutect2
- CSMD3 | c.9073C>T p.R3025C (on ENST00000297405 / NM_001363185.1; = p.R2856C on NM_052900.3) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775065918, COSV52095077; called by muse, varscan2
- CSTF1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1251578127, COSV53858290; called by muse, mutect2
- CTNS | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776658046, COSV50444778; called by muse, mutect2
- CTRB1 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 73/788 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99366696; called by muse, mutect2, varscan2
- CUX1 | c.1198C>T p.R400C (on ENST00000292535 / NM_181552.4; = p.R411C on NM_001913.5) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371301313, COSV52904941; called by muse, mutect2
- CWH43 | c.1658+2T>C p.X553_splice | Splice Site (SNP) | VAF 42/402 reads (10%) | catalogued as COSV56937393; called by muse, mutect2
- CXADR | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs374465561, COSV53027786; called by muse, mutect2, varscan2
- CYFIP1 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs764835760; called by muse, mutect2
- DAGLA | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57193778, COSV57197770; called by muse, mutect2
- DCAF11 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58108628; called by muse, mutect2
- DCAF12L1 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64421388; called by muse, mutect2
- DCAF4L1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs754119361, COSV60786850; called by muse, mutect2
- DCAF4L2 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV60477410; called by muse, mutect2
- DCSTAMP | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 41/588 reads (7%) | catalogued as rs200311973, COSV52576874; called by muse, mutect2
- DDX43 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64836558; called by muse, mutect2
- DENND4B | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.888); catalogued as COSV57841683; called by muse, mutect2
- DFFB | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs542622663, COSV58860568; called by muse, mutect2, varscan2
- DGAT2L6 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60717376; called by muse, mutect2, varscan2
- DHX29 | c.1999T>C p.S667P | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99287311; called by muse, mutect2
- DHX57 | c.4058A>G p.Q1353R | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99769568; called by muse, mutect2, varscan2
- DICER1 | c.4679C>T p.A1560V | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58617133; called by muse, mutect2, varscan2
- DIPK2B | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100933441; called by muse, mutect2
- DLD | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52737326; called by muse, mutect2
- DLEC1 | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200604389, COSV57297418; called by muse, mutect2, varscan2
- DLGAP2 | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.22); catalogued as rs542762184, COSV101422000; called by muse, mutect2
- DNAH17 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs780254027, COSV67750013; called by muse, mutect2, varscan2
- DNAH2 | c.5972G>A p.R1991H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201098580, COSV66717227; called by mutect2, varscan2
- DNAH8 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as rs142959082, COSV59434250, COSV59455704; called by muse, mutect2, varscan2
- DNAJB7 | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV53421184; called by muse, mutect2
- DNAJC13 | c.4319T>C p.L1440P | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53447807, COSV53452096; called by muse, mutect2
- DNAJC13 | c.5159C>T p.S1720L | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs753788665, COSV53447816; called by muse, mutect2, varscan2
- DNTTIP2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63283805; called by muse, mutect2, varscan2
- DPH5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59859190; called by muse, mutect2, varscan2
- DSCAML1 | c.1493C>T p.T498M (on ENST00000321322; = p.T438M on NM_020693.4) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs762502300, COSV58385823, COSV58385961; called by muse, mutect2
- DUS3L | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 27/557 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57833270, COSV57833769; called by muse, mutect2
- DUSP11 | c.217_219del p.K73del | In Frame Del (DEL) | VAF 30/286 reads (10%) | catalogued as rs769291574; called by pindel, varscan2
- DUSP21 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100173579; called by muse, mutect2
- DVL2 | c.1685G>A p.S562N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.982); catalogued as COSV50035169; called by muse, mutect2
- DYNC2H1 | c.9686G>A p.W3229* | Nonsense Mutation (SNP) | VAF 39/341 reads (11%) | catalogued as COSV62089888; called by muse, mutect2, varscan2
- DYRK3 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs782743574, COSV65605411; called by muse, mutect2
- ECM1 | c.71-2A>C p.X24_splice | Splice Site (SNP) | VAF 19/133 reads (14%) | catalogued as COSV60872308; called by muse, mutect2, varscan2
- EEF2K | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV53779821; called by muse, mutect2
- EFCAB3 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761208952, COSV59500713, COSV59501856; called by muse, mutect2, varscan2
- EFCAB5 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV100300277; called by muse, mutect2
- EFNB3 | c.224A>T p.N75I | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV99872737; called by muse, mutect2
- EFTUD2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765588398, COSV68183025; called by mutect2, varscan2
- EIF2AK1 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as rs754214883, COSV52237557; called by mutect2, varscan2
- EIF2AK3 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100303747; called by muse, mutect2
- EIF4A1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs865904208, COSV51510726; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157558201, COSV57514641; called by muse, mutect2, varscan2
- ELAC2 | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as rs1234751791, COSV52391226; called by muse, mutect2
- ELL3 | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV55855242; called by muse, mutect2
- EP400 | c.8612A>G p.Q2871R | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV57767722; called by muse, mutect2, varscan2
- EPB41L2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100440320, COSV61353986; called by muse, mutect2
- EPB41L4B | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 20/511 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV101000524; called by muse, mutect2
- EPG5 | c.5503A>G p.R1835G | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56346956; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 26/268 reads (10%) | catalogued as rs1317589623; called by mutect2, pindel
- EPHX2 | c.1349A>G p.Y450C | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs527892120, COSV66844259; called by muse, mutect2, varscan2
- EPS8 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs775283555, COSV55528918; called by muse, mutect2
- ERAP1 | c.2150C>T p.T717I | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV57086252; called by muse, mutect2
- ERLIN2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs780065091, COSV52419924; called by muse, varscan2
- EVC2 | c.2975A>G p.Q992R | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60390057; called by muse, mutect2, varscan2
- EXOSC10 | c.2354G>T p.S785I (on ENST00000376936 / NM_001001998.3; = p.S760I on NM_002685.4) | Missense Mutation (SNP) | VAF 58/1122 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs991324336, COSV100442558; called by muse, mutect2
- EXOSC3 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1325254462, COSV59203557; called by muse, mutect2
- F13A1 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 36/613 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV99343101; called by muse, mutect2
- FAM133B | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.953); catalogued as COSV70075413; called by muse, mutect2
- FAM13C | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 31/316 reads (10%) | catalogued as COSV53245461; called by muse, mutect2
- FAM78B | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV57976041; called by muse, mutect2
- FAM81A | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.831); catalogued as COSV55676907; called by muse, mutect2
- FAR1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV61384376; called by muse, mutect2
- FASTKD5 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766789581, COSV53904946; called by mutect2, varscan2
- FAT4 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67883159; called by muse, mutect2
- FBH1 | c.1123G>A p.V375M (on ENST00000362091 / NM_178150.3; = p.V426M on NM_032807.4) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs1052175453, COSV62982048; called by muse, mutect2
- FBXO31 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1294566807, COSV61148183; called by muse, mutect2, varscan2
- FCHO1 | c.763A>C p.S255R | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as COSV53181568; called by muse, mutect2
- FER1L6 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376662231; called by muse, mutect2, varscan2
- FGD6 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100676606; called by muse, mutect2
- FHDC1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1444917660, COSV52598741; called by muse, mutect2
- FKBP15 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53033088; called by muse, mutect2, varscan2
- FKBPL | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV100913572; called by muse, mutect2
- FLNA | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs782022718; called by muse, mutect2
- FLNA | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1453108649; called by muse, mutect2
- FLRT2 | c.1422G>T p.E474D | Missense Mutation (SNP) | VAF 37/458 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100420260, COSV58138539; called by muse, mutect2
- FMOD | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762152396, COSV61609806; called by muse, mutect2, varscan2
- FOXG1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV100486844; called by muse, mutect2
- FPGT-TNNI3K | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs780370068, COSV63042223; called by muse, mutect2, varscan2
- FUT6 | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV54605115; called by muse, mutect2, varscan2
- GAB2 | c.1828G>A p.G610S (on ENST00000361507 / NM_080491.3; = p.G572S on NM_012296.3) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs780858100, COSV100416172; called by muse, mutect2, varscan2
- GABRA3 | c.464A>C p.N155T | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100942755, COSV64805337; called by muse, mutect2
- GABRB2 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs375083192; ClinVar: uncertain significance; called by muse, mutect2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by mutect2, varscan2
- GALR1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55316432; called by muse, mutect2
- GASK1B | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56705669; called by muse, mutect2
- GCN1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as rs1364643792, COSV56105417; called by muse, mutect2
- GGA3 | c.915G>T p.E305D (on ENST00000537686 / NM_138619.4; = p.E272D on NM_014001.5) | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as COSV55455904; called by muse, mutect2
- GGN | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV53056444; called by muse, mutect2
- GGT1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs909690438; called by muse, mutect2, varscan2
- GIMAP1 | c.371T>C p.F124S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV56187571; called by muse, mutect2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 38/252 reads (15%) | catalogued as rs750227570; called by mutect2, varscan2
- GINS4 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs999237925, COSV52531101; called by muse, mutect2, varscan2
- GIT2 | c.2102G>A p.R701H (on ENST00000355312 / NM_057169.5; = p.R623H on NM_014776.5) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs753666949, COSV58079427; called by muse, mutect2
- GLG1 | c.3259G>A p.G1087R | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52665072; called by muse, mutect2, varscan2
- GNA14 | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100503007; called by muse, mutect2
- GPR137 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100464267; called by muse, mutect2
- GPX6 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724793; called by muse, mutect2
- GRM8 | c.1909T>A p.F637I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV58807913; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTF3C1 | c.3655C>T p.R1219W | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs184708220, COSV62239545; called by muse, mutect2
- H2AC16 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1163893579, COSV58898903, COSV58899509; called by muse, mutect2, varscan2
- HAPLN1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57146206, COSV57149438; called by muse, mutect2, varscan2
- HAUS3 | c.1182A>C p.E394D | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54722206; called by muse, mutect2
- HBA1 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 51/461 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as CD004925, COSV52265500; called by muse, mutect2, varscan2
- HDAC4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs1180905679, COSV61862078; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | catalogued as COSV100625709; called by mutect2, varscan2
- HECTD1 | c.6614G>A p.R2205H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs776580004, COSV67945612; called by muse, mutect2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 34/283 reads (12%) | catalogued as rs1218980629; called by mutect2, pindel, varscan2
- HID1 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as rs776593846, COSV60912697; called by muse, mutect2
- HIPK1 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs998340281, COSV61246799; called by muse, mutect2
- HNRNPUL1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV99647286; called by muse, mutect2
- HNRNPUL1 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 16/133 reads (12%) | catalogued as rs754580903, COSV54561158; called by muse, mutect2, varscan2
- HSD11B1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as rs200402963, COSV54825830, COSV99808217; called by muse, mutect2, varscan2
- HSD17B1 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV56797503; called by muse, mutect2
- HSPA1L | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989397; called by muse, mutect2
- HTR1E | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766560806, COSV100540916, COSV59507323; called by muse, mutect2
- HTR2A | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66326900; called by muse, mutect2
- HUWE1 | c.10100G>T p.R3367M | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as COSV53339352; called by muse, mutect2, varscan2
- HUWE1 | c.5137A>G p.K1713E | Missense Mutation (SNP) | VAF 46/554 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.899); catalogued as COSV53339399; called by muse, mutect2
- HYKK | c.772A>C p.S258R | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV66459780; called by muse, mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 20/177 reads (11%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- ICOS | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV57029183; called by muse, mutect2
- IFNL2 | c.503del p.K168Rfs*23 | Frame Shift Del (DEL) | VAF 25/233 reads (11%) | catalogued as rs1225989269; called by mutect2, pindel, varscan2
- IGF2R | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63627487; called by muse, mutect2, varscan2
- IKZF5 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64397358; called by muse, mutect2
- INHBC | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs1566551952, COSV59004807; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- ITGB4 | c.594C>A p.D198E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV52322249, COSV52323301; called by muse, mutect2, varscan2
- ITIH4 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as rs768593175, COSV56572496; called by muse, mutect2
- ITIH4 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56572515, COSV56577450; called by muse, mutect2
- ITIH5 | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | catalogued as rs374503043, COSV53667808; called by muse, mutect2
- ITPR3 | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1478853929, COSV100966846, COSV65407234; called by muse, mutect2, varscan2
- ITSN2 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 67/571 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764954537, COSV100743512; called by muse, mutect2, varscan2
- JAKMIP2 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 65/503 reads (13%) | catalogued as COSV54600293; called by muse, mutect2, varscan2
- JCAD | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 58/523 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.508); catalogued as rs775010422, COSV100948389, COSV100948391, COSV64758686; called by muse, mutect2, varscan2
- JHY | c.776dup p.N259Kfs*21 | Frame Shift Ins (INS) | VAF 14/128 reads (11%) | catalogued as rs756113544; called by mutect2, varscan2
- KATNIP | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs147867852; called by muse, mutect2
- KCNC3 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775504749, COSV65387034; called by muse, mutect2
- KCNMA1 | c.2449T>C p.W817R (on ENST00000286628 / NM_001161352.2; = p.W759R on NM_002247.4) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV54236819; called by muse, mutect2, varscan2
- KCNMB2 | c.605G>A p.W202* | Nonsense Mutation (SNP) | VAF 38/331 reads (11%) | catalogued as COSV64200646; called by muse, mutect2, varscan2
- KDM2B | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); catalogued as rs781846569, COSV100997424; called by muse, mutect2
- KDM4A | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs964749317, COSV64959101; called by muse, varscan2
- KDM5C | c.4472A>G p.E1491G | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64763701; called by muse, mutect2
- KDM6A | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 69/774 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV65038503; called by muse, mutect2
- KHDRBS3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV63415975; called by muse, mutect2, varscan2
- KLB | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57300806, COSV57304841; called by muse, mutect2, varscan2
- KLHL24 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54425172; called by muse, mutect2
- KLHL4 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64138997, COSV64140322; called by muse, mutect2
- KLHL4 | c.1777C>A p.H593N | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV64140331, COSV64144510; called by muse, mutect2, varscan2
- KLHL6 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58065182; called by muse, mutect2, varscan2
- KLRD1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201683513, COSV60273294; called by muse, mutect2
- KMT2D | c.15815C>T p.A5272V | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV56423223, COSV56464782; called by muse, mutect2, varscan2
- KMT5B | c.821-1G>A p.X274_splice | Splice Site (SNP) | VAF 18/341 reads (5%) | catalogued as COSV100069955; called by muse, mutect2
- KRT33B | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV52440550; called by muse, mutect2, varscan2
- KRT37 | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99845497; called by muse, mutect2
- KRT74 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV99977540; called by muse, mutect2
- KRT80 | c.256_258del p.E86del | In Frame Del (DEL) | VAF 17/158 reads (11%) | catalogued as rs777950129; called by pindel, varscan2
- LAMA1 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs545607128, COSV67534155; called by muse, mutect2, varscan2
- LAMA3 | c.3950G>A p.R1317H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs761970800, COSV58065473; called by muse, mutect2, varscan2
- LAMA4 | c.4696C>T p.R1566* (on ENST00000230538 / NM_001105206.3; = p.R1559* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as rs1554325261, COSV57893557; ClinVar: uncertain significance; called by muse, mutect2
- LAMA5 | c.9707C>T p.P3236L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs762372774, COSV53355944, COSV53359429; called by muse, mutect2, varscan2
- LAMC3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs773185472, COSV63089505; called by muse, mutect2, varscan2
- LAMP2 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV52352056; called by muse, mutect2, varscan2
- LARP4B | c.1048del p.Q350Sfs*9 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | catalogued as COSV100295692; called by mutect2, pindel, varscan2
- LCE1A | c.121T>G p.S41A | Missense Mutation (SNP) | VAF 64/615 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV58726734; called by muse, mutect2, varscan2
- LEFTY1 | c.842G>C p.W281S | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55282587; called by muse, mutect2, varscan2
- LMAN1L | c.907+1G>A p.X303_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as rs1252592547, COSV59001428; called by muse, mutect2
- LMTK3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV54310938; called by muse, mutect2
- LMTK3 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV54310956; called by muse, mutect2
- LPCAT3 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54641398; called by muse, mutect2, varscan2
- LRCH1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs141234801; called by muse, mutect2, varscan2
- LRP1 | c.10952-1G>A p.X3651_splice | Splice Site (SNP) | VAF 22/166 reads (13%) | catalogued as COSV54505703; called by muse, mutect2
- LRP10 | c.78T>C p.H26= | Splice Region (SNP) | VAF 20/187 reads (11%) | catalogued as rs899678283, COSV62077924; called by muse, mutect2, varscan2
- LRRC31 | c.1624del p.R542Efs*37 | Frame Shift Del (DEL) | VAF 50/442 reads (11%) | catalogued as rs748577734; called by mutect2, pindel, varscan2
- LRRTM2 | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51220398; called by muse, mutect2
- LUM | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57127772; called by muse, mutect2, varscan2
- LURAP1L | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754557712, COSV59984052; called by muse, mutect2, varscan2
- MACF1 | c.11332C>T p.Q3778* (on ENST00000372915; = p.Q1711* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV57113104; called by muse, mutect2
- MAG | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1176957300, COSV62699762; called by muse, mutect2
- MAGEA4 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52340735; called by muse, mutect2
- MAGEE1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV63909355; called by muse, mutect2
- MALT1 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779797395, COSV61933940; called by muse, mutect2, varscan2
- MAP3K9 | c.2660G>A p.R887H (on ENST00000554752 / NM_001284230.1; = p.R901H on NM_033141.4) | Missense Mutation (SNP) | VAF 44/546 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772906765, COSV67120600; called by muse, mutect2
- MARCHF10 | c.1115G>T p.R372M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV60886062; called by muse, mutect2
- MARCO | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59053058; called by muse, mutect2
- MASP1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.129); catalogued as COSV56221875; called by muse, mutect2, varscan2
- MAST1 | c.775-1G>T p.X259_splice | Splice Site (SNP) | VAF 11/150 reads (7%) | catalogued as COSV52243641; called by muse, mutect2
- MDGA1 | c.2263T>G p.F755V | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV51793602; called by muse, mutect2, varscan2
- MDH1 | c.763A>G p.R255G | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV51862896; called by muse, mutect2
- MDN1 | c.2825C>T p.T942I | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV101021378; called by muse, mutect2
- MED14 | c.2883G>A p.T961= | Splice Region (SNP) | VAF 15/120 reads (13%) | catalogued as COSV61356333; called by muse, mutect2, varscan2
- MED23 | c.3623C>T p.T1208M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs781433865, COSV63430677; called by muse, mutect2, varscan2
- MET | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV100577236; called by muse, mutect2
- MFAP2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65003691; called by muse, mutect2
- MFAP5 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1400247359, COSV63945150; called by muse, mutect2
- MGAT5 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV56095071; called by muse, mutect2, varscan2
- MIB2 | c.2053T>C p.S685P | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as COSV100598921; called by muse, mutect2
- MICAL3 | c.1840A>G p.M614V | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV52901671; called by muse, mutect2, varscan2
- MICALL1 | c.2234+1G>A p.X745_splice | Splice Site (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99317289; called by muse, mutect2
- MIDEAS | c.3126del p.K1042Nfs*51 | Frame Shift Del (DEL) | VAF 39/344 reads (11%) | catalogued as rs1168947806; called by mutect2, pindel, varscan2
- MPP3 | c.1075A>G p.M359V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101263337; called by muse, mutect2
- MPRIP | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763818544, COSV57926181; called by muse, mutect2, varscan2
- MR1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as rs763132197, COSV51580361; called by muse, mutect2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/225 reads (9%) | catalogued as rs768684761; called by mutect2, pindel
- MST1 | c.465T>A p.D155E | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.6); PolyPhen probably damaging (1); catalogued as COSV56532791; called by muse, mutect2
- MSX1 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66947123; called by muse, mutect2
- MTFR1L | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs1249301796, COSV65355650; called by muse, mutect2
- MUC16 | c.40193G>A p.R13398H | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.369); catalogued as rs764581423, COSV66689492; called by muse, mutect2
- MUC16 | c.35152G>A p.V11718I | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as COSV67454683, COSV67489089; called by muse, mutect2, varscan2
- MUC16 | c.19117A>G p.T6373A | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV67454693; called by muse, mutect2, varscan2
- MUC5B | c.8150del p.P2717Qfs*3 | Frame Shift Del (DEL) | VAF 66/586 reads (11%) | catalogued as rs1564942452; called by mutect2, varscan2
- MUC5B | c.10366G>A p.G3456R | Missense Mutation (SNP) | VAF 89/1859 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs764206254, COSV71594942; called by muse, mutect2
- MUC5B | c.15082G>A p.A5028T | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71590863; called by muse, mutect2
- MYO1F | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369105985; called by muse, mutect2, varscan2
- MYPOP | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 20/172 reads (12%) | catalogued as COSV59133310; called by muse, mutect2
- NAALAD2 | c.1686dup p.Q563Tfs*14 | Frame Shift Ins (INS) | VAF 35/301 reads (12%) | catalogued as rs1221515108; called by mutect2, pindel, varscan2
- NCAM1 | c.1133C>T p.S378L (on ENST00000316851 / NM_181351.5; = p.S368L on NM_000615.7) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868954902, COSV57515779; called by muse, mutect2
- NCOA6 | c.2914G>T p.G972C | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV62862346; called by muse, varscan2
- NEB | c.17989C>A p.L5997I | Missense Mutation (SNP) | VAF 60/501 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.192); catalogued as COSV50888052; called by muse, mutect2, varscan2
- NEFM | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55331301; called by muse, mutect2
- NHLH2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867911589, COSV57201713; called by muse, mutect2
- NIBAN2 | c.1622T>C p.V541A | Missense Mutation (SNP) | VAF 48/478 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV100031534; called by muse, mutect2
- NLE1 | c.1212C>T p.G404= | Splice Region (SNP) | VAF 15/159 reads (9%) | catalogued as COSV50100868; called by muse, mutect2
- NLGN3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1459104193, COSV100704793; called by muse, mutect2
- NOSIP | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100182281; called by muse, mutect2
- NOTCH4 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV66679623; called by muse, mutect2
- NPAS1 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV53409106; called by muse, mutect2, varscan2
- NPAS3 | c.1949C>T p.T650M (on ENST00000356141 / NM_001164749.2; = p.T618M on NM_022123.3) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV60826477; called by muse, mutect2
- NPR3 | c.1609C>A p.H537N (on ENST00000265074 / NM_001364458.2; = p.H536N on NM_000908.4) | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54090138, COSV99423027; called by muse, mutect2
- NR0B1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV66763798; called by muse, mutect2
- NR0B1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as COSV66763669; called by muse, mutect2
- NR1H4 | c.299G>A p.R100H (on ENST00000551379 / NM_001206993.2; = p.R90H on NM_005123.4) | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs113431969, COSV51850072, COSV51850512, COSV51856383; called by muse, mutect2, varscan2
- NREP | c.205del p.*69Nfs*59 | Frame Shift Del (DEL) | VAF 14/164 reads (9%) | catalogued as COSV57405086; called by mutect2, pindel
- NRXN2 | c.3538C>T p.R1180W | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026176052, COSV55447523, COSV55463973; called by muse, mutect2
- NTAN1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55073930; called by muse, mutect2
- NTN4 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs778122235, COSV59218296; called by muse, mutect2, varscan2
- NUGGC | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58433465; called by muse, mutect2
- NUP155 | c.272C>A p.P91H (on ENST00000231498 / NM_153485.3; = p.P32H on NM_004298.4) | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99192912; called by muse, mutect2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 26/167 reads (16%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP54 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1333851368, COSV99345310, COSV99345490; called by muse, mutect2
- NUP58 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1466535112, COSV67751107; called by muse, mutect2, varscan2
- OAZ3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs753420523, COSV58617705; called by muse, mutect2, varscan2
- OBSL1 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs369418075; called by muse, mutect2
- OGFRL1 | c.322-2A>G p.X108_splice | Splice Site (SNP) | VAF 14/103 reads (14%) | catalogued as COSV64971781; called by muse, mutect2, varscan2
- OR10C1 | c.613G>T p.A205S (on ENST00000622521; = p.A203S on NM_013941.3) | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs774923628, COSV65822432, COSV65823074; called by muse, mutect2, varscan2
- OR2AT4 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV59406610; called by muse, mutect2, varscan2
- OR4A5 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); catalogued as COSV100156917, COSV60522020; called by muse, mutect2
- OR51I1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1443676010, COSV100971339; called by muse, mutect2
- OR5B3 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV100511999; called by muse, mutect2
- OR5F1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53546026, COSV53549348; called by muse, mutect2
- OR6B3 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60116223; called by muse, mutect2
- OR6C65 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV65568290; called by muse, mutect2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- P4HA2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs202201315, COSV51324145; called by muse, mutect2, varscan2
- PABPC3 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 33/340 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs747031541, COSV55798558; called by muse, mutect2
- PADI3 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.2); catalogued as rs369350547; called by muse, mutect2
- PAFAH2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs902766750, COSV100959270; called by muse, mutect2
- PAK4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as rs921822315, COSV58944459; called by muse, mutect2
- PATJ | c.2869T>C p.S957P | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57158167; called by muse, mutect2
- PAX3 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV60587074; called by muse, mutect2
- PAX7 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs776359965, COSV64749114, COSV64750156; called by muse, mutect2
- PCDH10 | c.303C>G p.N101K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99993651; called by muse, mutect2
- PCDH10 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.991); catalogued as COSV52090252; called by muse, varscan2
- PCDH15 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57280127; called by muse, mutect2
- PCDHA11 | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV56486695; called by muse, mutect2, varscan2
- PCDHA7 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV65343045; called by muse, mutect2
- PCDHB8 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 32/513 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.061); catalogued as COSV99176987; called by muse, mutect2
- PCDHGA4 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1261694629, COSV53919019; called by muse, mutect2, varscan2
- PCDHGB2 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV53898871, COSV53919037; called by muse, mutect2
- PCDHGB5 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53919050; called by muse, mutect2, varscan2
- PCLO | c.2264A>C p.K755T | Missense Mutation (SNP) | VAF 75/856 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV61623952; called by muse, mutect2
- PCNP | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 54/576 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54575316; called by muse, mutect2
- PCSK4 | c.1069-1G>T p.X357_splice | Splice Site (SNP) | VAF 24/162 reads (15%) | catalogued as COSV56298685; called by muse, mutect2, varscan2
- PDE1B | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54489829; called by muse, mutect2
- PDE4A | c.1807C>T p.R603C (on ENST00000380702 / NM_001111307.2; = p.R364C on NM_006202.3) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs756425710, COSV53352447; called by muse, mutect2, varscan2
- PDGFRA | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1060501501, COSV57267741; ClinVar: uncertain significance; called by muse, mutect2
- PDZD2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs200521349, COSV56854237; called by muse, mutect2, varscan2
- PER1 | c.2542C>A p.P848T | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100424579; called by muse, mutect2
- PEX11B | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); catalogued as COSV57162073; called by muse, mutect2, varscan2
- PHC1 | c.2832G>T p.E944D | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.6); catalogued as COSV99134215; called by muse, mutect2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA1 | c.3007A>C p.M1003L | Missense Mutation (SNP) | VAF 62/576 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59803838; called by muse, mutect2, varscan2
- PHKB | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144689991, COSV54517570; called by muse, mutect2, varscan2
- PIH1D2 | c.193dup p.I65Nfs*34 | Frame Shift Ins (INS) | VAF 26/270 reads (10%) | catalogued as rs1466112244; called by mutect2, pindel
- PIK3C2G | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56816856; called by muse, mutect2
- PITPNM3 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs752312346, COSV52593946; called by muse, mutect2, varscan2
- PKN1 | c.2681C>T p.T894M | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs746308814, COSV52874775; called by muse, mutect2
- PKP2 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV99297790; called by muse, mutect2
- PLCD4 | c.906C>A p.C302* | Nonsense Mutation (SNP) | VAF 28/272 reads (10%) | catalogued as COSV68842055; called by muse, mutect2, varscan2
- PLEKHM2 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV65395631; called by muse, mutect2, varscan2
- PLK4 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54636868; called by muse, mutect2, varscan2
- PLOD2 | c.2194G>A p.V732M | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334066975, COSV51463251; called by muse, mutect2
- PLS3 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99171709; called by muse, mutect2
- PLXNA3 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV63753556; called by muse, mutect2
- PLXNA3 | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100860003; called by muse, mutect2
- PNPLA1 | c.637A>G p.M213V (on ENST00000394571 / NM_001374623.1; = p.M118V on NM_173676.2) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs746320168, COSV57233403; called by mutect2, varscan2
- PNPLA7 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs749612902, COSV52996512, COSV99479991; called by muse, mutect2
- POLQ | c.6763G>A p.D2255N | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423012946, COSV51748415, COSV99953138; called by muse, mutect2
- POLRMT | c.2676G>A p.W892* | Nonsense Mutation (SNP) | VAF 40/359 reads (11%) | catalogued as COSV52113457; called by muse, mutect2, varscan2
- POM121C | c.3429C>A p.F1143L (on ENST00000607367; = p.F901L on NM_001099415.3) | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV57544844; called by muse, mutect2
- POMGNT2 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60953004; called by muse, mutect2
- POT1 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205880072, COSV62928889, COSV62936844; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARA | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1337407585, COSV53077649; called by muse, mutect2
- PPFIA3 | c.2657G>A p.S886N | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100494946; called by muse, mutect2, varscan2
- PPL | c.2967del p.Q990Rfs*31 | Frame Shift Del (DEL) | VAF 34/319 reads (11%) | catalogued as rs762995701; called by mutect2, pindel, varscan2
- PPP6R2 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV53291493; called by muse, mutect2
- PRAG1 | c.3643A>G p.S1215G | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58159275; called by muse, mutect2, varscan2
- PRAME | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101287094; called by muse, mutect2, varscan2
- PREP | c.1745A>G p.H582R (on ENST00000369110; = p.H648R on NM_002726.5) | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64869677; called by muse, mutect2
- PRIM2 | c.337T>A p.S113T | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV99227970; called by muse, mutect2
- PRKCSH | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52950795; called by muse, mutect2
- PRKD3 | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99306200, COSV99306899; called by muse, mutect2
- PROCA1 | c.500G>A p.C167Y (on ENST00000439862 / NM_001366301.1; = p.C139Y on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99972726; called by muse, mutect2
- PRPF31 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58084836; called by muse, mutect2
- PRPF8 | c.3422G>A p.R1141H | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322560435, COSV59261858; called by muse, mutect2, varscan2
- PRR30 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV53205255; called by muse, mutect2
- PRRC2A | c.6170C>T p.P2057L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1472989800, COSV52988997; called by muse, mutect2
- PRRT2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs1567380661, COSV54882024; called by muse, mutect2
- PRUNE2 | c.8617G>A p.E2873K | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374420474; called by muse, mutect2
- PRXL2A | c.218del p.N73Mfs*4 | Frame Shift Del (DEL) | VAF 13/172 reads (8%) | catalogued as COSV64690809; called by mutect2, pindel
- PSG6 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as rs373770366; called by muse, mutect2
- PSMB4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51850426; called by muse, mutect2, varscan2
- PTCHD1 | c.2231T>C p.L744S | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101037705; called by muse, mutect2
- PTGES3L-AARSD1 | c.688T>C p.W230R (on ENST00000421990 / NM_001136042.2; = p.W212R on NM_025267.3) | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64182226; called by muse, mutect2
- PTGFR | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV66114675; called by muse, mutect2, varscan2
- PTGS2 | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV66568140; called by muse, mutect2, varscan2
- PTPN6 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59683437; called by muse, mutect2
- PTPRJ | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.514); catalogued as rs769547786, COSV69250699; called by muse, mutect2
- PTPRK | c.3708+1G>A p.X1236_splice (on ENST00000368215 / NM_001291984.2; = p.X1237_splice on NM_002844.4) | Splice Site (SNP) | VAF 8/86 reads (9%) | catalogued as rs1304323697, COSV63893791; called by muse, mutect2
- RAB11B | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60085428; called by muse, mutect2
- RAB2A | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52910468; called by muse, mutect2, varscan2
- RAB34 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1266060351, COSV56385750; called by muse, mutect2
- RAB3IP | c.518G>A p.G173D (on ENST00000550536 / NM_175623.4; = p.G157D on NM_022456.5) | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99923274; called by muse, mutect2
- RABGAP1 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100438592; called by muse, mutect2
- RAC2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1415916204, COSV50773868; called by muse, mutect2
- RAG1 | c.2176T>C p.S726P | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV55023792, COSV55024395; called by muse, mutect2
- RASEF | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100906894; called by muse, mutect2
- RBFOX1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs199644500, COSV100300321, COSV60951913; called by muse, mutect2, varscan2
- RBM10 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100237859; called by muse, mutect2
- RBM19 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866674770, COSV55693808; called by muse, mutect2
- RBM4B | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336450208, COSV100026460; called by muse, mutect2
- RBMS2 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV56263930; called by muse, mutect2
- RBMXL2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1305327865, COSV100182657, COSV60979046; called by muse, mutect2
- RBP3 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as rs202076554; called by muse, mutect2, varscan2
- RBP3 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs375761633; ClinVar: uncertain significance; called by muse, mutect2
- RD3 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs755218137, COSV65362073; called by muse, mutect2
- REEP5 | c.66_68del p.L23del | In Frame Del (DEL) | VAF 19/115 reads (17%) | catalogued as rs1561663084; called by mutect2, pindel, varscan2
- RFPL1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100585764; called by muse, mutect2, varscan2
- RFPL3 | c.361C>T p.R121W (on ENST00000249007 / NM_001098535.1; = p.R92W on NM_006604.2) | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs139344772; called by muse, mutect2, varscan2
- RGS19 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250333459, COSV58657415; called by muse, mutect2
- RIBC1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs1556893207, COSV51447724; called by muse, mutect2, varscan2
- RIOK3 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as rs949681301, COSV59772488; called by muse, mutect2, varscan2
- RMND5B | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 21/230 reads (9%) | catalogued as rs746249251, COSV57744108; called by muse, mutect2
- RNF123 | c.3241C>A p.L1081M | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57537967; called by muse, mutect2
- RNF139 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV52678460; called by muse, mutect2, varscan2
- RNF151 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV58399490; called by muse, mutect2
- RNF186 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV64296721; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 45/219 reads (21%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1303374273, COSV54338473; called by muse, mutect2
- RPS4X | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs748321540, COSV60181583, COSV60182216; called by muse, mutect2, varscan2
- RPTN | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 202/2063 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768986867, COSV60166732; called by muse, mutect2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | catalogued as rs747510098; called by mutect2, varscan2
- RTN4RL1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs765195768, COSV58674855; called by muse, mutect2
- RXFP3 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1192931492, COSV57504665; called by muse, mutect2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 37/360 reads (10%) | catalogued as rs759920279; called by mutect2, pindel
- SAFB2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 20/211 reads (9%) | catalogued as COSV53041253; called by muse, mutect2
- SALL3 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73305889; called by muse, mutect2
- SALL3 | c.2874G>T p.E958D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as rs979846131, COSV73305890; called by muse, mutect2
- SCN9A | c.4141C>T p.R1381* (on ENST00000303354; = p.R1370* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 26/315 reads (8%) | catalogued as rs748159444, COSV57604480; called by muse, mutect2
- SDK1 | c.3565A>G p.S1189G | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101269404, COSV67387928; called by muse, mutect2
- SDS | c.602T>C p.F201S | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99981058; called by muse, mutect2
- SEC24B | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99493587; called by muse, mutect2
- SELP | c.2131A>G p.K711E | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55249901, COSV99741470; called by muse, mutect2
- SEMA3G | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 36/432 reads (8%) | catalogued as COSV51594534; called by muse, mutect2
- SENP7 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); catalogued as COSV100053281; called by muse, mutect2
- SERPINA5 | c.183del p.S62Afs*9 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | catalogued as COSV61575071; called by mutect2, pindel
- SERPINB8 | c.575dup p.T193Dfs*7 | Frame Shift Ins (INS) | VAF 20/145 reads (14%) | catalogued as rs1568275935; called by mutect2, varscan2
- SESN3 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781016923, COSV53583899, COSV99565871; called by muse, mutect2, varscan2
- SEZ6 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57978335; called by muse, mutect2, varscan2
- SH2D3C | c.2350C>T p.R784C (on ENST00000314830 / NM_170600.3; = p.R627C on NM_005489.4) | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1304844231, COSV59120565; called by muse, mutect2, varscan2
- SH2D5 | c.752G>A p.R251H (on ENST00000444387 / NM_001103161.2; = p.R167H on NM_001103160.2) | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745377516, COSV66706421; called by muse, mutect2
- SH3PXD2A | c.1291C>T p.R431C (on ENST00000369774 / NM_001365079.1; = p.R403C on NM_014631.2) | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370598379; called by muse, mutect2, varscan2
- SH3RF1 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1442664719, COSV52919337; called by muse, mutect2
- SHANK2 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53590887; called by muse, mutect2, varscan2
- SHROOM4 | c.4122A>C p.K1374N | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56786693; called by muse, mutect2, varscan2
- SHROOM4 | c.3589G>T p.G1197C | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV99173575; called by muse, mutect2, varscan2
- SI | c.4789A>T p.M1597L | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV100015664; called by muse, mutect2
- SI | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750727226, COSV52271250, COSV52279533; called by muse, mutect2
- SINHCAF | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61797126; called by muse, mutect2, varscan2
- SLC17A5 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100867078; called by muse, mutect2
- SLC19A3 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as rs1247579454, COSV51451975; called by muse, mutect2, varscan2
- SLC1A6 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55669064; called by muse, mutect2, varscan2
- SLC25A37 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs1423433639, COSV51563792; called by muse, mutect2
- SLC35A2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs376547003, COSV54429268; ClinVar: benign; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 32/258 reads (12%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC43A3 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371491685; called by muse, mutect2, varscan2
- SLC4A3 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553552538, COSV56091193; ClinVar: uncertain significance; called by muse, mutect2
- SLC52A2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57351316; called by muse, mutect2
- SLC6A12 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100675118; called by muse, mutect2
- SLC6A2 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs11568341; called by muse, mutect2, varscan2
- SLC8A1 | c.1948A>G p.I650V | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs200952740, COSV60474810; called by muse, varscan2
- SLCO3A1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59227114; called by muse, mutect2
- SLCO4A1 | c.1747T>A p.F583I | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53889833; called by muse, mutect2
- SLITRK5 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61521776; called by muse, mutect2, varscan2
- SMTN | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 32/286 reads (11%) | catalogued as rs762131666, COSV60776469; called by muse, mutect2, varscan2
- SNRNP70 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99672315; called by muse, mutect2
- SNX18 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766025431, COSV57988546; called by muse, mutect2
- SNX27 | c.737-1G>T p.X246_splice | Splice Site (SNP) | VAF 50/477 reads (10%) | catalogued as COSV64325901; called by muse, mutect2, varscan2
- SOGA1 | c.2498G>A p.S833N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52914405; called by muse, mutect2, varscan2
- SPATA46 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62633252; called by muse, mutect2
- SPEF2 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs754396158, COSV61544205; called by muse, mutect2
- SPEN | c.6507G>T p.M2169I | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65361323; called by muse, mutect2
- SPON1 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as rs1564944794, COSV100115925, COSV59960424; called by muse, mutect2, varscan2
- SPRR2G | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 15/196 reads (8%) | PolyPhen benign (0.246); catalogued as COSV100907385; called by muse, mutect2
- SRCAP | c.6329G>A p.R2110H | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311592643, COSV52669564; called by muse, mutect2, varscan2
- SRGAP3 | c.2830A>G p.T944A | Missense Mutation (SNP) | VAF 26/632 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.899); catalogued as COSV100840982; called by muse, mutect2
- ST6GAL2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | PolyPhen benign (0.005); catalogued as COSV64526997; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | PolyPhen probably damaging (0.98); catalogued as rs763902940, COSV56570918; called by muse, mutect2, varscan2
- STAC | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV56208353; called by muse, mutect2, varscan2
- STARD3 | c.1138C>A p.R380= | Splice Region (SNP) | VAF 8/112 reads (7%) | catalogued as COSV59223244; called by muse, mutect2
- STK16 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs548466076, COSV50277899; called by muse, mutect2, varscan2
- STOM | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 33/591 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs1248813911, COSV99713675; called by muse, mutect2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 15/128 reads (12%) | catalogued as rs762120842, COSV51992441; called by mutect2, pindel, varscan2
- STRN | c.659+1G>A p.X220_splice | Splice Site (SNP) | VAF 34/319 reads (11%) | catalogued as rs1337335720, COSV55746809; called by muse, mutect2, varscan2
- STRN4 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99623665; called by muse, mutect2
- SYF2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1270566630, COSV52573217; called by muse, varscan2
- SYNE1 | c.15571C>T p.R5191C (on ENST00000367255 / NM_182961.4; = p.R5120C on NM_033071.3) | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99565567; called by muse, mutect2
- SYNE2 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 20/473 reads (4%) | catalogued as COSV100647759; called by muse, mutect2
- TAAR6 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51583014; called by muse, mutect2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 19/149 reads (13%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TAS2R19 | c.808A>G p.M270V | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs755104738, COSV101114899; called by muse, mutect2
- TAS2R38 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV71885196; called by muse, mutect2, varscan2
- TATDN3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as rs989514049, COSV65324925; called by muse, mutect2
- TCERG1 | c.2614C>T p.R872* | Nonsense Mutation (SNP) | VAF 79/653 reads (12%) | catalogued as COSV57035073; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 35/273 reads (13%) | catalogued as rs758822980; called by mutect2, varscan2
- TCIRG1 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as rs773690722, COSV55834954; called by muse, mutect2, varscan2
- TCP11 | c.88del p.Q30Rfs*19 (on ENST00000512012; = p.Q30Rfs*14 on NM_001261817.2) | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | catalogued as rs751330115; called by mutect2, pindel, varscan2
- TDG | c.553T>A p.Y185N | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV57165665; called by muse, mutect2
- TDRD6 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1293322370, COSV100287671; called by muse, mutect2, varscan2
- TDRD6 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373561239, COSV60173778; called by muse, mutect2
- TENM1 | c.5696G>A p.R1899Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs753712664, COSV64428027; called by muse, mutect2, varscan2
- TFAP2C | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.296); catalogued as COSV52370284; called by muse, mutect2
- THAP9 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV56355977; called by muse, mutect2, varscan2
- THBS1 | c.1502G>A p.W501* | Nonsense Mutation (SNP) | VAF 19/229 reads (8%) | catalogued as COSV52950923, COSV52951428; called by muse, mutect2
- TLE2 | c.1460A>G p.Q487R | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV53579042; called by muse, mutect2
- TLR3 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1418733023, COSV99711030; called by muse, mutect2, varscan2
- TLR9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1330761016, COSV59725993; called by muse, mutect2
- TMEM255A | c.355-2A>G p.X119_splice | Splice Site (SNP) | VAF 35/300 reads (12%) | catalogued as COSV100550374; called by muse, mutect2, varscan2
- TNFAIP3 | c.1871G>A p.C624Y | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52797626; called by muse, mutect2, varscan2
- TPD52 | c.542T>C p.V181A (on ENST00000379097 / NM_001025252.3; = p.V141A on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66949973; called by muse, mutect2
- TPO | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs780371451, COSV61097890; called by muse, mutect2
- TPR | c.6803T>C p.V2268A | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV66600264; called by muse, mutect2
- TRANK1 | c.8750G>A p.R2917Q | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs779860547, COSV57145147; called by muse, mutect2, varscan2
- TRANK1 | c.5539G>T p.E1847* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57145170; called by muse, mutect2
- TRIM33 | c.2896T>C p.C966R | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61821564; called by muse, mutect2, varscan2
- TRIP12 | c.1613T>C p.V538A | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52261068; called by muse, mutect2, varscan2
- TRRAP | c.1995T>A p.N665K | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100722521; called by muse, mutect2
- TRRAP | c.6190G>A p.A2064T (on ENST00000359863 / NM_001244580.1; = p.A2046T on NM_003496.3) | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV62841608; called by muse, mutect2
- TSHZ3 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs770738477, COSV53664420; called by muse, mutect2
- TSHZ3 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 56/521 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV99551722; called by muse, varscan2
- TSNARE1 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.132); catalogued as COSV56172783; called by muse, mutect2
- TSPYL4 | c.468del p.K156Nfs*23 | Frame Shift Del (DEL) | VAF 24/253 reads (9%) | catalogued as rs1178402530; called by mutect2, pindel
- TTC21A | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369092746; called by muse, mutect2
- TTLL4 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs533198956, COSV51435540; called by muse, mutect2
- TTN | c.72923C>T p.T24308I (on ENST00000591111; = p.T16884I on NM_003319.4) | Missense Mutation (SNP) | VAF 34/358 reads (9%) | PolyPhen possibly damaging (0.524); catalogued as COSV59955011; called by muse, mutect2
- TTN | c.49729C>T p.R16577* (on ENST00000591111; = p.R9153* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/259 reads (7%) | catalogued as rs775367836, COSV100601106, COSV60424296; called by muse, mutect2
- TTN | c.15677C>A p.A5226D (on ENST00000591111; = p.A4299D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | PolyPhen possibly damaging (0.827); catalogued as COSV59955090; called by muse, mutect2
- TTYH3 | c.1051A>G p.N351D | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51859303; called by muse, mutect2
- TUBGCP3 | c.2568T>C p.G856= | Splice Region (SNP) | VAF 34/438 reads (8%) | catalogued as COSV56185453; called by muse, mutect2
- TULP4 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV65573688; called by muse, mutect2, varscan2
- TXNL4A | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 27/386 reads (7%) | catalogued as COSV54099358; called by muse, mutect2
- UBC | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs763615606, COSV100298992; called by muse, mutect2, varscan2
- UNC13D | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV52883599, COSV52886799; called by muse, mutect2, varscan2
- UPF1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53194655; called by muse, mutect2, varscan2
- USH2A | c.11161G>A p.G3721R | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56440855; called by muse, mutect2
- USP43 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53300849; called by muse, mutect2, varscan2
- VASP | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV55606272; called by muse, mutect2
- VBP1 | c.286-1G>T p.X96_splice | Splice Site (SNP) | VAF 8/90 reads (9%) | catalogued as COSV53972056; called by muse, mutect2
- VCPIP1 | c.2840G>A p.G947D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV60046421; called by muse, mutect2, varscan2
- VEZT | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs908308174, COSV54137289, COSV54141754; called by muse, mutect2, varscan2
- VMP1 | c.1159A>G p.M387V | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs1205913678, COSV51865747, COSV51873696; called by muse, mutect2, varscan2
- VN1R5 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs779845357; called by muse, mutect2, varscan2
- VPS13A | c.3338del p.K1113Rfs*30 | Frame Shift Del (DEL) | VAF 29/249 reads (12%) | catalogued as rs1454445683, COSV62425680; called by mutect2, pindel, varscan2
- VTN | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs781794013, COSV56872592; called by muse, mutect2, varscan2
- WDR17 | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54570726, COSV99706693; called by muse, mutect2, varscan2
- WDR25 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs529381627, COSV58935194; called by muse, mutect2, varscan2
- WDR5B | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV51657579; called by muse, mutect2, varscan2
- WDR6 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs776455367, COSV58244400; called by muse, mutect2, varscan2
- WIZ | c.4216G>A p.A1406T (on ENST00000673675 / NM_001371589.1; = p.A311T on NM_021241.3) | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.22); catalogued as COSV54606109; called by muse, mutect2, varscan2
- WNK4 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs369907969; called by muse, mutect2, varscan2
- WWOX | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 63/596 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749277249, COSV68347995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XK | c.56C>G p.T19R | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV101064625, COSV66119868; called by muse, mutect2
- XRCC6 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs749612494, COSV63752556; called by muse, mutect2, varscan2
- ZBP1 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs755567669, COSV59060922; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 26/184 reads (14%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX3 | c.10937G>A p.C3646Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV51712964; called by muse, mutect2, varscan2
- ZFP36L1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.581); catalogued as COSV60544837; called by muse, mutect2
- ZKSCAN2 | c.1915A>G p.S639G | Missense Mutation (SNP) | VAF 37/490 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV100048216; called by muse, mutect2
- ZKSCAN5 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.783); catalogued as COSV100460201; called by muse, mutect2
- ZMYM3 | c.2555C>G p.S852C | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58736870; called by muse, mutect2, varscan2
- ZNF131 | c.1000G>T p.E334* (on ENST00000509156 / NM_001330707.2; = p.E300* on NM_003432.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/268 reads (6%) | catalogued as COSV100185496; called by muse, mutect2
- ZNF341 | c.2141C>T p.A714V (on ENST00000375200 / NM_001282935.1; = p.A707V on NM_032819.4) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs1255897683, COSV61007343; called by muse, mutect2
- ZNF37A | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.811); catalogued as COSV61072937, COSV61073686; called by muse, mutect2, varscan2
- ZNF443 | c.911C>G p.T304S | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV56890899; called by muse, mutect2, varscan2
- ZNF445 | c.3056C>T p.S1019L | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs771397082, COSV68538620; called by muse, mutect2, varscan2
- ZNF609 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV58581565; called by muse, mutect2
- ZNF619 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.584); catalogued as COSV100123307; called by muse, mutect2
- ZNF653 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53402397; called by muse, mutect2
- ZNF664 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV61877467; called by muse, mutect2, varscan2
- ZNF676 | c.646C>A p.L216I (on ENST00000650058; = p.L184I on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV68092584; called by muse, mutect2, varscan2
- ZNF776 | c.650T>C p.F217S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV57814815; called by muse, mutect2
- ZSCAN5A | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54225284; called by muse, mutect2
- ZSWIM5 | c.1426A>C p.S476R | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV62733286; called by muse, mutect2, varscan2
- ABCC2 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- ACACA | c.5135G>A p.R1712Q | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACIN1 | c.809_810del p.E270Gfs*13 | Frame Shift Del (DEL) | VAF 31/248 reads (13%) | called by pindel, varscan2
- ACTL6B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- AHNAK2 | c.12616del p.L4206Cfs*19 | Frame Shift Del (DEL) | VAF 31/264 reads (12%) | called by mutect2, varscan2
- AKAP11 | c.2755del p.S919Pfs*33 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel
- ALG8 | c.396del p.V133Wfs*24 | Frame Shift Del (DEL) | VAF 20/205 reads (10%) | called by mutect2, pindel, varscan2
- AMPD3 | c.648del p.N217Tfs*42 (on ENST00000396553 / NM_001025389.2; = p.N226Tfs*42 on NM_000480.3) | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- ANGPT4 | c.390del p.M131Cfs*2 | Frame Shift Del (DEL) | VAF 32/259 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARMT1 | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ATM | c.6908del p.K2303Rfs*7 | Frame Shift Del (DEL) | VAF 27/251 reads (11%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.1047del p.F349Lfs*8 | Frame Shift Del (DEL) | VAF 21/189 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1F | c.3631-1G>A p.X1211_splice | Splice Site (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- CCDC116 | c.210dup p.G71Wfs*9 | Frame Shift Ins (INS) | VAF 22/182 reads (12%) | called by mutect2, pindel, varscan2
- CCDC34 | c.158_163del p.P53_P54del | In Frame Del (DEL) | VAF 17/144 reads (12%) | called by mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 25/198 reads (13%) | called by mutect2, pindel, varscan2
- CHRNA6 | c.813del p.V272* | Frame Shift Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- COG2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- COL4A3 | c.171del p.G58Vfs*35 | Frame Shift Del (DEL) | VAF 23/248 reads (9%) | called by mutect2, pindel
- CSMD2 | c.3501del p.F1167Lfs*6 | Frame Shift Del (DEL) | VAF 24/264 reads (9%) | called by mutect2, pindel
- CTTNBP2 | c.4911G>T p.R1637S | Missense Mutation (SNP) | VAF 21/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CUL9 | c.4449G>T p.Q1483H | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CUL9 | c.6258_6259del p.C2087Lfs*7 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by pindel, varscan2
- CYP4X1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.344); called by muse, mutect2
- DDAH2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- DNAH8 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- DNAJC14 | c.1457T>A p.V486D | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2
- DOCK11 | c.5322dup p.E1775* | Frame Shift Ins (INS) | VAF 52/469 reads (11%) | called by mutect2, varscan2
- DSCAM | c.648del p.F216Lfs*44 | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | called by mutect2, pindel, varscan2
- ENC1 | c.1496del p.G499Vfs*26 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | called by mutect2, varscan2
- EPHA6 | c.859dup p.A287Gfs*21 | Frame Shift Ins (INS) | VAF 36/355 reads (10%) | called by mutect2, varscan2
- EPHX2 | c.1546del p.R516Gfs*19 | Frame Shift Del (DEL) | VAF 45/305 reads (15%) | called by mutect2, pindel, varscan2
- ERBB4 | c.1798dup p.A600Gfs*10 | Frame Shift Ins (INS) | VAF 50/485 reads (10%) | called by pindel, varscan2
- FBXO34 | c.358del p.I120Lfs*13 | Frame Shift Del (DEL) | VAF 20/177 reads (11%) | called by mutect2, pindel, varscan2
- FBXO43 | c.1228del p.R410Efs*13 | Frame Shift Del (DEL) | VAF 83/576 reads (14%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GABBR1 | c.2061G>A p.W687* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- GPR87 | c.37A>G p.N13D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2
- GTF2IRD2B | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 66/1016 reads (6%) | called by muse, mutect2
- ICA1L | c.1368del p.W456Cfs*29 | Frame Shift Del (DEL) | VAF 19/184 reads (10%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.1021T>C p.*341Qext*43 | Nonstop Mutation (SNP) | VAF 19/333 reads (6%) | called by muse, mutect2
- KCNH4 | c.2943del p.Y982Tfs*24 | Frame Shift Del (DEL) | VAF 24/168 reads (14%) | called by mutect2, pindel, varscan2
- KDM7A | c.2748del p.G917Efs*15 | Frame Shift Del (DEL) | VAF 43/451 reads (10%) | called by mutect2, pindel
- KLF17 | c.307del p.Q103Kfs*9 | Frame Shift Del (DEL) | VAF 19/181 reads (10%) | called by mutect2, pindel, varscan2
- LARP4B | c.1338_1341del p.I446Mfs*45 | Frame Shift Del (DEL) | VAF 20/172 reads (12%) | called by pindel, varscan2
- MADD | c.68del p.P23Rfs*30 | Frame Shift Del (DEL) | VAF 45/385 reads (12%) | called by mutect2, pindel, varscan2
- MAGEH1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- MAP3K5 | c.3395_3396del p.F1132Wfs*8 | Frame Shift Del (DEL) | VAF 20/203 reads (10%) | called by mutect2, varscan2
- MMP10 | c.632_635del p.L211Sfs*23 | Frame Shift Del (DEL) | VAF 26/210 reads (12%) | called by mutect2, pindel
- MROH1 | c.979del p.L327Wfs*2 | Frame Shift Del (DEL) | VAF 31/293 reads (11%) | called by mutect2, pindel, varscan2
- MROH1 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.768); called by muse, mutect2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 27/299 reads (9%) | called by mutect2, pindel
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/173 reads (11%) | called by mutect2, varscan2
- OPTN | c.624C>T p.G208= | Splice Region (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- OR1S2 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/221 reads (12%) | called by mutect2, pindel
- PEAK1 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 24/224 reads (11%) | called by mutect2, pindel, varscan2
- PELI1 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); called by muse, mutect2
- PIANP | c.404dup p.H136Sfs*16 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- PIGR | c.1815del p.F605Lfs*225 | Frame Shift Del (DEL) | VAF 26/216 reads (12%) | called by mutect2, pindel, varscan2
- PINK1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by muse, mutect2
- PNISR | c.2250dup p.H751Tfs*5 | Frame Shift Ins (INS) | VAF 55/591 reads (9%) | called by mutect2, pindel
284 further variants in this file (36 protein-altering or splice-affecting, 230 silent, 18 other) are not listed here.
